Gene-level copy-number profile of tumor specimen TCGA-AA-3494-01A from TCGA case TCGA-AA-3494, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.0 years (20,089 days).
Specimen TCGA-AA-3494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.1ec2f0dc-516c-48c2-b2b3-211258cd7fac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3494-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e0396ab-35b3-4efe-bdc7-eb443a94e423

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 865; copy number 2: 12,122; copy number 3: 31,028; copy number 4: 11,559; copy number 5: 1,677; copy number 6: 7; copy number 7: 511; copy number 8: 1,948; copy number 9: 91; copy number 14: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3494-01): tumor purity 0.74, ploidy 3.23, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,561 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,900,016–141,195,808, 1,427 genes, copy number 8–14 (within-gene range 5–14) (broad region; genes not listed).
- chr8:142,111,414–145,066,685, 168 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–39,329,924, 856 genes, copy number 7–8 (broad region; genes not listed).
- chr20:40,685,848–45,410,610, 109 genes, copy number 8–9 (broad region; genes not listed).
- chr20:45,425,510–45,425,573, 1 gene, copy number 9: MIR6812.

Autosomal genes at a single copy (total copy number 1): 865. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
